Gene-level copy-number profile of tumor specimen BLGSP-71-22-00347-01A from CGCI case BLGSP-71-22-00347, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt-like lymphoma; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 7.8 years (2,857 days).
Specimen BLGSP-71-22-00347-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e24131ee-4dcc-4e4e-b792-ce405deb47e5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-22-00347-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,756 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second AscatNGS file.
https://portal.gdc.cancer.gov/files/5df8d00d-48db-4206-ab7c-32c228324439

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 3,852; copy number 2: 53,390; copy number 3: 1,546; copy number 4: 38; copy number 5: 1; copy number 6: 1; copy number 12: 1; copy number 16: 2; copy number 28: 5.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,825,207, 2 genes (within-gene range 0–2): MALLP2, MIR4436A.
- chr22:22,738,944–22,905,025, 29 genes (within-gene range 0–1): IGLV3-17, IGLV3-15, IGLV2-14, IGLV3-13, IGLV3-12, AC244157.1, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571, IGLL5, IGLJ1, IGLC1, IGLJ2, IGLC2, IGLJ3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:21,298,233–21,325,241, 2 genes, copy number 16 (within-gene range 1–16): AC068446.2, RNU6-1235P.
- chr15:21,843,750–21,981,245, 7 genes, copy number 6–28: MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P.
- chr21:12,999,676–13,016,692, 1 gene, copy number 5: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 1,050. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
